Somatic mutation profile of tumor specimen C3L-00928-03 (aliquot CPT0063570009_1) from CPTAC case C3L-00928, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 58.6 years (21,418 days).
Specimen C3L-00928-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f4b1411-8e46-4991-ab6d-20eff7707873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00928-31 (Blood Derived Normal), aliquot CPT0065280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a51c3218-b994-4a16-a6c7-21be6ffb304a

The open-access MAF lists 33 somatic variants for this specimen: 23 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/433 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 44/569 reads (8%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- DOHH | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 70/817 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs368504297; called by muse, mutect2
- FAT2 | c.8909A>T p.K2970M | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1481957280; called by muse, mutect2
- FBXW11 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 49/782 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV51611631; called by muse, mutect2
- GNAS | c.185T>G p.I62S | Missense Mutation (SNP) | VAF 37/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55685506; called by muse, mutect2
- KCNH7 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs139430414; called by muse, mutect2
- LRTM1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 52/503 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs779554165, COSV55513807; called by muse, mutect2, varscan2
- NR4A3 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 27/390 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs778148069, COSV58243692; called by muse, mutect2
- OAF | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs748586285, COSV61110148; called by muse, mutect2
- OR13F1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 44/595 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs143065377; called by muse, mutect2
- SSC5D | c.4553G>A p.R1518H | Missense Mutation (SNP) | VAF 100/1012 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs748017648, COSV67476898; called by muse, mutect2
- ZIC4 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 66/751 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs998956801, COSV67172689; called by muse, mutect2
- ARHGEF28 | c.2624T>C p.F875S | Missense Mutation (SNP) | VAF 34/640 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ITK | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 90/875 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITPR2 | c.7637A>T p.D2546V | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8B2 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 34/467 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2
- PCDHB2 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 50/794 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.242); called by muse, mutect2
- SETX | c.5313T>G p.N1771K | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SRCIN1 | c.1654G>A p.V552I (on ENST00000621492; = p.V518I on NM_025248.3) | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- SVEP1 | c.8835A>C p.K2945N | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TRIP12 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 49/773 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- TRPC6 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDHR1 | c.1353G>A p.K451= | Silent (SNP) | VAF 79/835 reads (9%) | called by muse, mutect2
- CNTN2 | c.2220C>T p.N740= | Silent (SNP) | VAF 41/423 reads (10%) | called by muse, mutect2
- CNTN5 | c.381C>A p.G127= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs1183378558; called by muse, mutect2
- COL5A1 | c.840C>T p.Y280= | Silent (SNP) | VAF 63/820 reads (8%) | catalogued as rs765347784, COSV65669270, COSV65675824; called by muse, mutect2
- EXD3 | c.1422G>A p.T474= | Silent (SNP) | VAF 41/563 reads (7%) | catalogued as rs370478324; called by muse, mutect2
- HOXB1 | c.288T>A p.S96= | Silent (SNP) | VAF 53/750 reads (7%) | called by muse, mutect2
- OR51C1P | c.168C>T p.H56= | Silent (SNP) | VAF 14/188 reads (7%) | catalogued as rs193262556; called by muse, mutect2
- PKD1L1 | c.6666A>G p.E2222= | Silent (SNP) | VAF 36/387 reads (9%) | called by muse, mutect2
- ZFP82 | c.1422C>T p.G474= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as rs202056836; called by muse, mutect2
- LMBR1L | c.72+730G>A | Intron (SNP) | VAF 29/306 reads (9%) | catalogued as rs1380526903; called by muse, mutect2
